Somatic mutation profile of tumor specimen a8955d38-7a72-4f9d-9c70-5c0f08 (aliquot a8955d38-7a72-4f9d-9c70-5c0f08_D6) from CPTAC case 05CO006, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB.
Specimen a8955d38-7a72-4f9d-9c70-5c0f08: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63d85f46-a422-4370-af00-b3a3b84c4f8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0a182bf2-b58f-4152-b9b2-459e08 (Blood Derived Normal), aliquot 0a182bf2-b58f-4152-b9b2-459e08_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22306ce6-bf1a-4a1e-91b4-b6eb128b6c6d

The open-access MAF lists 1,425 somatic variants for this specimen: 939 protein-altering or splice-affecting, 277 silent, 209 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 620, Silent 277, Frame Shift Del 212, Intron 104, 3'UTR 43, Frame Shift Ins 40, Nonsense Mutation 25, RNA 20, 5'UTR 20, Splice Site 18, In Frame Del 13, 5'Flank 11.

Variants (750 of 1,425; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.457T>G p.L153V | Missense Mutation (SNP) | VAF 163/491 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs180177223, CM042933; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B3GALT6 | c.588del p.R197Afs*81 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs533071750, COSV55420617; ClinVar: pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 36/130 reads (28%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FLNC | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 20/352 reads (6%) | catalogued as rs1420159591; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 150/406 reads (37%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- GTF2I | c.1319A>G p.N440S (on ENST00000573035 / NM_032999.4; = p.N399S on NM_001518.5) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | hotspot (GDC flag); SIFT tolerated (0.17); PolyPhen probably damaging (0.952); catalogued as rs1135649, COSV60399702; called by muse, mutect2
- LARP7 | c.1213del p.T405Qfs*5 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs750946801; ClinVar: likely pathogenic; called by mutect2, varscan2
- MYO7A | c.397dup p.H133Pfs*7 | Frame Shift Ins (INS) | VAF 42/175 reads (24%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIGO | c.2361dup p.T788Hfs*5 | Frame Shift Ins (INS) | VAF 36/135 reads (27%) | catalogued as rs770591449; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SUFU | c.71del p.P24Rfs*72 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs587776579; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AATK | c.1366G>A p.D456N (on ENST00000326724 / NM_001080395.3; = p.D353N on NM_004920.2) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as rs770682190, COSV58685564; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA7 | c.2530G>A p.G844R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs371982554, CM166832; called by muse, mutect2, varscan2
- ABCC11 | c.3952C>T p.R1318C | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs149406807; called by muse, mutect2, varscan2
- ABL1 | c.2494del p.H832Tfs*11 | Frame Shift Del (DEL) | VAF 28/115 reads (24%) | catalogued as COSV59326685; called by mutect2, pindel, varscan2
- ACAD11 | c.2242C>T p.R748* | Nonsense Mutation (SNP) | VAF 42/103 reads (41%) | catalogued as rs753836523, COSV99051858; called by muse, mutect2, varscan2
- ACTG2 | c.85del p.R29Gfs*16 | Frame Shift Del (DEL) | VAF 42/117 reads (36%) | catalogued as rs751325833; called by mutect2, pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 33/59 reads (56%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM8 | c.1281dup p.E428Rfs*17 | Frame Shift Ins (INS) | VAF 24/70 reads (34%) | catalogued as rs753471255; called by mutect2, varscan2
- ADAMTS16 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.543); catalogued as rs1224232723, COSV56987708; called by muse, mutect2, varscan2
- ADAMTS5 | c.769C>T p.R257W | Missense Mutation (SNP) | VAF 67/218 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs1381117530, COSV53175273; called by muse, mutect2, varscan2
- ADAMTS7 | c.1654C>T p.R552W | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs765813251; called by muse, mutect2, varscan2
- ADGRD2 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs906751756; called by muse, mutect2, varscan2
- ADGRL2 | c.1596G>T p.K532N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1170099299; called by muse, mutect2, varscan2
- AFP | c.1043del p.N348Ifs*22 | Frame Shift Del (DEL) | VAF 49/156 reads (31%) | catalogued as rs779815391; called by mutect2, pindel, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP8L | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 116/335 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1284132473; called by muse, mutect2, varscan2
- AKAP9 | c.3758A>G p.Q1253R | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as rs1243392476; called by muse, mutect2, varscan2
- ALDH9A1 | c.1189A>G p.M397V | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs761333115; called by muse, mutect2, varscan2
- AMOTL2 | c.818del p.P273Lfs*13 | Frame Shift Del (DEL) | VAF 38/107 reads (36%) | catalogued as rs1319526303; called by mutect2, pindel, varscan2
- ANK3 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs770844854; called by muse, mutect2, varscan2
- ANKK1 | c.2040A>T p.E680D | Missense Mutation (SNP) | VAF 105/343 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs961308840; called by muse, mutect2, varscan2
- ANKRD18A | c.323C>T p.A108V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV68802156; called by muse, mutect2, varscan2
- ANKRD33B | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1283765258; called by muse, mutect2, varscan2
- ANKRD36 | c.2375C>T p.T792M | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); catalogued as rs201600563, COSV70739052; called by muse, mutect2, varscan2
- ANKRD36B | c.1352del p.K451Rfs*17 | Frame Shift Del (DEL) | VAF 52/206 reads (25%) | catalogued as rs767587871; called by mutect2, varscan2
- ANLN | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs774583975; called by muse, mutect2, varscan2
- APOB | c.9284A>G p.Q3095R | Missense Mutation (SNP) | VAF 55/220 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748849856, COSV51927252; called by muse, mutect2, varscan2
- ARG1 | c.221G>A p.G74E | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM128109, COSV51581162; called by muse, mutect2, varscan2
- ARHGAP45 | c.3322G>A p.V1108M | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.403); catalogued as rs142667237; called by muse, mutect2, varscan2
- ARHGAP6 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs757326649; called by muse, mutect2, varscan2
- ARHGEF1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1555846533; called by muse, mutect2, varscan2
- ARHGEF28 | c.3527G>A p.R1176H | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs889538743, COSV55256734; called by muse, mutect2, varscan2
- ARID1A | c.2402del p.G801Vfs*32 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | catalogued as COSV61388445; called by mutect2, pindel, varscan2
- ARL14EP | c.266del p.N89Ifs*4 | Frame Shift Del (DEL) | VAF 48/166 reads (29%) | catalogued as rs1247324796; called by mutect2, varscan2
- ASB18 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs1474552993; called by muse, mutect2, varscan2
- ASPM | c.6374C>T p.A2125V | Missense Mutation (SNP) | VAF 143/442 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54127006; called by muse, mutect2, varscan2
- ATAD1 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57757564; called by muse, mutect2, varscan2
- ATAD5 | c.5053A>G p.T1685A | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs751642439; called by muse, mutect2, varscan2
- ATF5 | c.109dup p.L37Pfs*5 | Frame Shift Ins (INS) | VAF 20/73 reads (27%) | catalogued as rs768611141; called by mutect2, pindel, varscan2
- ATP10D | c.1848del p.L617Cfs*41 | Frame Shift Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs764067652, COSV56705401; called by mutect2, pindel, varscan2
- ATXN7L3 | c.1004C>T p.P335L (on ENST00000389384 / NM_001382309.1; = p.P342L on NM_001382308.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs776406810, COSV100116092; called by muse, mutect2, varscan2
- B3GALT1 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs749376311, COSV59909342; called by muse, mutect2, varscan2
- B3GNT6 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.338); catalogued as rs781990020; called by muse, mutect2, varscan2
- BCL6 | c.1418del p.P473Rfs*117 | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | catalogued as COSV51655892; called by mutect2, pindel, varscan2
- BCL9L | c.1354del p.Q452Sfs*11 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | catalogued as rs756382429; called by mutect2, pindel
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs752427670; called by mutect2, varscan2
- BICD2 | c.1487G>A p.R496H | Missense Mutation (SNP) | VAF 133/390 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs1312330865, COSV63548231; called by muse, varscan2
- BST2 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV53090003; called by muse, mutect2, varscan2
- C10orf71 | c.2776C>T p.R926C | Missense Mutation (SNP) | VAF 55/223 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs796132086, COSV60507846; called by muse, mutect2, varscan2
- C10orf71 | c.4049G>A p.R1350H | Missense Mutation (SNP) | VAF 99/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1287157255, COSV60506726; called by muse, mutect2, varscan2
- C11orf58 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1198004760; called by muse, mutect2, varscan2
- C19orf81 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); catalogued as COSV53265220; called by muse, mutect2, varscan2
- C2CD6 | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53799304; called by muse, mutect2, varscan2
- C5orf52 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.666); catalogued as rs200431937; called by muse, mutect2, varscan2
- CACNA1D | c.5440G>A p.D1814N (on ENST00000350061 / NM_001128840.3; = p.D1834N on NM_000720.4) | Missense Mutation (SNP) | VAF 127/467 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.018); catalogued as rs767284638; called by muse, mutect2, varscan2
- CACNA1G | c.2923C>T p.R975W | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs201831777; called by muse, mutect2, varscan2
- CACNA1G | c.6394C>T p.R2132C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs780662520, COSV100661258; called by muse, mutect2, varscan2
- CACNA1H | c.1582C>T p.H528Y | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs990227397; called by muse, mutect2, varscan2
- CACNA1S | c.5120C>A p.P1707H | Missense Mutation (SNP) | VAF 112/315 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100754901; called by mutect2, varscan2
- CAMK1G | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1478490067, COSV50527115; called by muse, mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 15/67 reads (22%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMTA1 | c.2779G>T p.A927S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57922011; called by muse, mutect2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 30/73 reads (41%) | catalogued as rs745547658; called by mutect2, varscan2
- CAND2 | c.1058G>A p.R353Q (on ENST00000456430 / NM_001162499.2; = p.R260Q on NM_012298.3) | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770572224; called by muse, mutect2, varscan2
- CAPN5 | c.304C>T p.R102C (on ENST00000456580; = p.R62C on NM_004055.5) | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1555036994; called by muse, mutect2, varscan2
- CAPNS1 | c.721+1G>A p.X241_splice | Splice Site (SNP) | VAF 61/194 reads (31%) | catalogued as rs760597333, COSV53084409; called by muse, mutect2, varscan2
- CARMIL2 | c.1253dup p.Q419Afs*112 | Frame Shift Ins (INS) | VAF 19/72 reads (26%) | catalogued as rs764374356; called by mutect2, pindel, varscan2
- CARMIL3 | c.2946dup p.R983Qfs*29 | Frame Shift Ins (INS) | VAF 25/107 reads (23%) | catalogued as rs749244991; called by mutect2, varscan2
- CASQ2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 83/292 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs750680032, COSV99797786; called by muse, mutect2, varscan2
- CAT | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs1376887882; called by muse, mutect2, varscan2
- CAVIN2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 101/331 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.301); catalogued as rs749460076; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC136 | c.1388C>T p.T463M | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs564211780, COSV52801795; called by muse, mutect2, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC34 | c.391_393del p.E131del | In Frame Del (DEL) | VAF 28/82 reads (34%) | catalogued as rs1269705762; called by pindel, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC81 | c.845G>A p.R282Q (on ENST00000445632 / NM_001156474.2; = p.R192Q on NM_021827.4) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs139764574; called by muse, mutect2, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs781790231; called by mutect2, varscan2
- CCNY | c.554C>T p.T185M | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146495735; called by muse, mutect2, varscan2
- CD163 | c.2303C>T p.A768V | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV63131953, COSV63137996; called by muse, mutect2, varscan2
- CDC42 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.429); catalogued as COSV100212766; called by muse, mutect2, varscan2
- CDCA4 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 68/217 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs373693056; called by muse, mutect2, varscan2
- CDH22 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs774356645, COSV64836824; called by muse, mutect2, varscan2
- CDH22 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.085); catalogued as rs1218255173, COSV64836482, COSV64839245; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs1325731082; called by mutect2, varscan2
- CHFR | c.842C>T p.A281V (on ENST00000432561 / NM_001161345.1; = p.A240V on NM_018223.2) | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs745889598; called by muse, mutect2, varscan2
- CHML | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs772929547, COSV100087376; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 28/95 reads (29%) | catalogued as rs369752219; called by mutect2, varscan2
- CMIP | c.757C>T p.R253W (on ENST00000537098 / NM_198390.2; = p.R159W on NM_030629.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as rs750221720, COSV101220950; called by muse, mutect2, varscan2
- CNN1 | c.371T>G p.L124R | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV52956469; called by muse, mutect2, varscan2
- COL14A1 | c.3067A>G p.K1023E | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as rs1490138138; called by muse, mutect2, varscan2
- COL22A1 | c.3926G>A p.G1309D | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277747; called by muse, mutect2, varscan2
- COL9A2 | c.1242del p.G415Efs*116 | Frame Shift Del (DEL) | VAF 30/114 reads (26%) | catalogued as rs756694568; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- CRHR1 | c.334del p.S112Afs*92 (on ENST00000398285 / NM_001145146.2; = p.S112Afs*63 on NM_004382.5) | Frame Shift Del (DEL) | VAF 23/105 reads (22%) | catalogued as rs746467817; called by mutect2, pindel, varscan2
- CSF2RA | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 65/271 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.285); catalogued as rs755930892; called by muse, mutect2, varscan2
- CTU2 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192246487; called by muse, mutect2, varscan2
- CUBN | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 124/402 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs376195863; called by muse, mutect2, varscan2
- CUBN | c.466dup p.C156Lfs*15 | Frame Shift Ins (INS) | VAF 56/179 reads (31%) | catalogued as rs755846379; called by mutect2, varscan2
- CUL1 | c.625G>A p.V209M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV57390015; called by muse, mutect2, varscan2
- CXXC1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV53276489; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYP24A1 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 101/197 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs768937201; called by muse, mutect2, varscan2
- CYP4F22 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 171/530 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.732); catalogued as rs773295754, COSV99512903; called by muse, mutect2, varscan2
- DAP3 | c.217dup p.Q73Pfs*24 | Frame Shift Ins (INS) | VAF 26/93 reads (28%) | catalogued as rs757230517; called by mutect2, pindel, varscan2
- DBF4 | c.1223del p.K408Sfs*16 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs749089320; called by mutect2, pindel, varscan2
- DCAF4L2 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 109/502 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1191833620, COSV60479414; called by muse, mutect2, varscan2
- DCUN1D5 | c.670_672del p.L224del | In Frame Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs980245838; called by pindel, varscan2
- DIAPH3 | c.3431C>T p.T1144M | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.081); catalogued as rs1439410037; called by muse, mutect2, varscan2
- DIDO1 | c.6661G>A p.A2221T | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); catalogued as rs201786226, COSV99827256; called by muse, mutect2, varscan2
- DISP3 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1043672614, COSV53829013; called by muse, mutect2
- DLX3 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 97/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420553846; called by muse, mutect2, varscan2
- DNAH14 | c.8085del p.A2696Lfs*25 (on ENST00000445597; = p.A3499Lfs*25 on NM_001367479.1) | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | catalogued as rs940159934; called by mutect2, pindel, varscan2
- DNAH5 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 95/282 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as rs371414060; called by muse, mutect2, varscan2
- DNAH6 | c.4787C>T p.A1596V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1409277123; called by muse, mutect2, varscan2
- DNAH8 | c.5533G>A p.A1845T | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs756311363, COSV59433688; called by muse, mutect2, varscan2
- DNAH9 | c.10066G>A p.A3356T | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.103); catalogued as COSV52365321; called by muse, mutect2, varscan2
- DNAI3 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); catalogued as rs146956293; called by muse, mutect2, varscan2
- DNASE1L1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 96/320 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1557187287, COSV50010782; called by muse, mutect2, varscan2
- DSP | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 110/297 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777763456, COSV101131912, COSV65792008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP5 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1411766291; called by muse, mutect2, varscan2
- DUXB | c.344del p.N115Tfs*3 | Frame Shift Del (DEL) | VAF 11/92 reads (12%) | catalogued as rs956480172; called by mutect2, pindel, varscan2
- DVL2 | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs374072094; called by muse, mutect2, varscan2
- DYRK1A | c.1286T>C p.V429A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as rs770275081; called by muse, mutect2, varscan2
- DZIP3 | c.1778T>C p.I593T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV64312083; called by muse, mutect2, varscan2
- E2F5 | c.320del p.K107Sfs*11 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs761281897; called by mutect2, pindel, varscan2
- EFEMP2 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 165/393 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1008465800, COSV57260378; ClinVar: uncertain significance; called by muse, varscan2
- EFTUD2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1487772387, COSV68184358; called by muse, mutect2, varscan2
- EIF4E1B | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867316543, COSV100024801; called by muse, mutect2, varscan2
- ELAC1 | c.717A>T p.L239F | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as rs201796024; called by muse, mutect2, varscan2
- EMILIN3 | c.1380del p.W461Gfs*21 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs759858342; called by mutect2, varscan2
- ENTPD1 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 83/246 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64603496; called by muse, mutect2, varscan2
- EP300 | c.1881G>A p.A627= | Splice Region (SNP) | VAF 29/101 reads (29%) | catalogued as rs1299332607, COSV54327200, COSV99608779; called by muse, mutect2, varscan2
- EPHA1 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770915770, COSV51976174; called by muse, mutect2, varscan2
- EPM2AIP1 | c.710G>T p.S237I | Missense Mutation (SNP) | VAF 72/226 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV51625294; called by muse, mutect2, varscan2
- ERFE | c.341del p.P114Lfs*20 | Frame Shift Del (DEL) | VAF 85/269 reads (32%) | catalogued as rs35861371; called by mutect2, pindel, varscan2
- EXOC6 | c.850del p.S284Pfs*56 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | catalogued as COSV53318711; called by mutect2, pindel
- FAM131B | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs374651528; called by muse, mutect2, varscan2
- FAM13B | c.2346dup p.E783* | Frame Shift Ins (INS) | VAF 20/81 reads (25%) | catalogued as rs1203077575; called by mutect2, varscan2
- FAM149A | c.69del p.A24Qfs*180 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | catalogued as rs1438345086; called by mutect2, pindel, varscan2
- FAM184B | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs887243309; called by muse, mutect2, varscan2
- FAT4 | c.4229T>C p.V1410A | Missense Mutation (SNP) | VAF 77/228 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1388012345; called by muse, mutect2, varscan2
- FBXO10 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.04); catalogued as rs778677445, COSV52832111; called by muse, mutect2, varscan2
- FBXW8 | c.290C>T p.A97V (on ENST00000309909; = p.A135V on NM_012174.1) | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1054013262; called by muse, mutect2, varscan2
- FCHO2 | c.44del p.N15Ifs*11 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs768979093, COSV55110370; called by mutect2, pindel, varscan2
- FCMR | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as rs763799731, COSV65567697; called by muse, mutect2, varscan2
- FDPS | c.561+5T>C | Splice Region (SNP) | VAF 36/101 reads (36%) | catalogued as rs374801518; called by muse, mutect2, varscan2
- FILIP1L | c.1678G>A p.V560I (on ENST00000354552 / NM_182909.3; = p.V320I on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs777759195, COSV58767363, COSV58771709; called by muse, mutect2, varscan2
- FLG | c.9835G>A p.A3279T | Missense Mutation (SNP) | VAF 194/726 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.037); catalogued as rs115482787, COSV64246012; called by muse, varscan2
- FLNA | c.4449G>T p.L1483F | Missense Mutation (SNP) | VAF 122/465 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1356756921; called by muse, mutect2, varscan2
- FLOT2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV67528829; called by muse, mutect2, varscan2
- FMR1 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54427348; called by muse, mutect2, varscan2
- FOXA1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 33/342 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs917539237; called by muse, mutect2
- FRAS1 | c.1421C>T p.T474M | Missense Mutation (SNP) | VAF 132/428 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.841); catalogued as rs748242409, COSV53615616; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 15/52 reads (29%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSIP2 | c.8038del p.T2680Hfs*3 | Frame Shift Del (DEL) | VAF 26/97 reads (27%) | catalogued as rs755234663; called by mutect2, varscan2
- FTCD | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs1267304494; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs756304971; called by mutect2, varscan2
- GABRR2 | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.409); catalogued as rs371695052, COSV68765388; called by muse, mutect2, varscan2
- GAP43 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751087225, COSV59344154, COSV59346415; called by muse, mutect2, varscan2
- GAPDHS | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 24/91 reads (26%) | catalogued as rs145487252; called by muse, mutect2, varscan2
- GDPD2 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 44/151 reads (29%) | catalogued as rs762413277; called by muse, mutect2, varscan2
- GFM1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs765130908; called by muse, mutect2, varscan2
- GIMAP1 | c.851del p.G284Afs*39 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | catalogued as rs756722011, COSV100212336; called by mutect2, pindel, varscan2
- GINS3 | c.482C>T p.T161I | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs768266760; called by muse, mutect2, varscan2
- GJB5 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 141/459 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.079); catalogued as rs766705310, COSV58356358; called by muse, mutect2, varscan2
- GLG1 | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52672059, COSV99215366; called by muse, mutect2, varscan2
- GNB3 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369984083; called by muse, mutect2, varscan2
- GOLGA5 | c.1608G>T p.E536D | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV99371015; called by muse, mutect2, varscan2
- GPATCH3 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407598703, COSV104424053; called by muse, mutect2, varscan2
- GPR108 | c.1156G>A p.E386K (on ENST00000264080 / NM_001080452.1; = p.E144K on NM_020171.2) | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs369212248; called by muse, mutect2, varscan2
- GPR148 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 103/332 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV59308995; called by muse, mutect2, varscan2
- GREB1 | c.1847T>C p.L616P | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52197051; called by muse, mutect2, varscan2
- GSE1 | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); catalogued as rs766630200; called by muse, mutect2, varscan2
- GSE1 | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1001121552; called by muse, mutect2, varscan2
- GYPC | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 63/233 reads (27%) | catalogued as COSV99392156; called by muse, mutect2, varscan2
- HAP1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs782595996; called by muse, mutect2, varscan2
- HDAC7 | c.2069G>T p.R690L (on ENST00000427332; = p.R729L on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV50318770; called by muse, mutect2, varscan2
- HEATR1 | c.1972G>A p.G658S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs767113628; called by muse, mutect2, varscan2
- HECW1 | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 85/278 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.619); catalogued as rs1562984403, COSV67835102; called by muse, mutect2, varscan2
- HIC1 | c.1513C>T p.R505W (on ENST00000322941 / NM_001098202.1; = p.R486W on NM_006497.4) | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53979090; called by muse, mutect2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 42/158 reads (27%) | catalogued as rs755016625; called by mutect2, varscan2
- IDH2 | c.435dup p.T146Dfs*126 | Frame Shift Ins (INS) | VAF 100/380 reads (26%) | catalogued as rs747216375; ClinVar: uncertain significance; called by mutect2, varscan2
- IFITM2 | c.274G>A p.V92M | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.097); catalogued as rs751280068; called by muse, mutect2, varscan2
- IFNB1 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.231); catalogued as rs142435111; called by muse, mutect2, varscan2
- IFT140 | c.3638C>T p.T1213M | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1384059687; called by muse, mutect2, varscan2
- IGHMBP2 | c.1349G>A p.R450H | Missense Mutation (SNP) | VAF 125/389 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs771485988; called by muse, mutect2, varscan2
- INSC | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs192722337, COSV65411271; called by muse, mutect2, varscan2
- IQGAP1 | c.2822del p.N941Ifs*8 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs771739474; called by mutect2, varscan2
- IRAK1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 64/215 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs782144624; called by muse, mutect2, varscan2
- IRS1 | c.1791dup p.H598Afs*13 | Frame Shift Ins (INS) | VAF 16/62 reads (26%) | catalogued as rs761880048; called by mutect2, varscan2
- ITFG2 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 103/283 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs772993429; called by muse, mutect2, varscan2
- ITGA11 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 73/264 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs535301460, COSV59875670; called by muse, varscan2
- ITGB2 | c.1318A>G p.T440A (on ENST00000302347; = p.T416A on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/467 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs766736050; called by muse, mutect2, varscan2
- JAK3 | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV71686238; called by muse, mutect2, varscan2
- JAK3 | c.578G>A p.C193Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.999); catalogued as rs1467075214, CM136732; called by muse, mutect2, varscan2
- JPH3 | c.2134G>A p.E712K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs748839170; called by muse, varscan2
- JRK | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 108/440 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs782558295; called by muse, mutect2, varscan2
- KCNG2 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs769822846, COSV60266568; called by muse, mutect2, varscan2
- KCNH1 | c.2216G>A p.R739H (on ENST00000271751 / NM_172362.3; = p.R712H on NM_002238.4) | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as rs1356477648; called by muse, mutect2, varscan2
- KCNH2 | c.2785del p.E929Rfs*45 | Frame Shift Del (DEL) | VAF 46/172 reads (27%) | catalogued as CD097541; called by mutect2, pindel, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 39/117 reads (33%) | catalogued as rs142280183; called by mutect2, varscan2
- KIAA1109 | c.10773del p.K3591Nfs*12 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs1261303645; called by mutect2, pindel, varscan2
- KIF26A | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747228794, COSV59464441; called by muse, mutect2, varscan2
- KIF26A | c.4085del p.P1362Rfs*24 | Frame Shift Del (DEL) | VAF 38/149 reads (26%) | catalogued as rs776136395; called by pindel, varscan2
- KMT2A | c.7286G>A p.G2429E | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs782600770; called by muse, mutect2, varscan2
- KMT5C | c.124del p.L42Cfs*15 | Frame Shift Del (DEL) | VAF 32/101 reads (32%) | catalogued as rs769842795; called by mutect2, pindel, varscan2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 40/131 reads (31%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRT24 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1446720777, COSV99232100; called by muse, mutect2, varscan2
- KRT3 | c.1834G>A p.G612S | Missense Mutation (SNP) | VAF 65/192 reads (34%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as rs1210592376; called by muse, mutect2, varscan2
- KRT7 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs762446937, COSV100081377; called by muse, mutect2, varscan2
- KY | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV71016937; called by muse, mutect2, varscan2
- LAMC2 | c.3458G>A p.R1153K | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371544411; called by muse, mutect2, varscan2
- LAMC3 | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as rs376158532, COSV100735905; called by muse, mutect2, varscan2
- LARGE1 | c.332G>A p.S111N | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV61667924; called by muse, mutect2, varscan2
- LEAP2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs183124357; called by muse, mutect2, varscan2
- LLGL1 | c.2396G>A p.R799H | Missense Mutation (SNP) | VAF 102/394 reads (26%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.996); catalogued as rs780909473, COSV57501011; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 48/162 reads (30%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNX2 | c.1460G>A p.R487K | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.18); catalogued as rs940502260; called by mutect2, varscan2
- LRGUK | c.1937A>G p.Y646C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs756431045; called by muse, mutect2, varscan2
- LRRIQ3 | c.702T>A p.N234K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs535898263, COSV63045798; called by muse, mutect2, varscan2
- MADD | c.4928G>A p.R1643Q | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs778945803; called by muse, mutect2, varscan2
- MAN2A2 | c.3115C>T p.R1039C | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs570702789; called by muse, mutect2, varscan2
- MAN2B2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs545720173; called by muse, mutect2, varscan2
- MAPK8IP2 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1224168485; called by muse, mutect2, varscan2
- MARCHF4 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as rs745717127; called by muse, mutect2, varscan2
- MCF2L | c.1601G>A p.R534Q (on ENST00000375608; = p.R502Q on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373448735; called by muse, mutect2, varscan2
- MDGA2 | c.1397C>T p.P466L (on ENST00000399232 / NM_001113498.2; = p.P168L on NM_182830.4) | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.401); catalogued as rs1001049845, COSV62077688; called by muse, mutect2, varscan2
- MED25 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 108/314 reads (34%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.3); catalogued as COSV57203251; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 15/81 reads (19%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEF2D | c.1427del p.G476Dfs*35 | Frame Shift Del (DEL) | VAF 59/183 reads (32%) | catalogued as COSV61727950; called by mutect2, pindel, varscan2
- MEIS1 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99715451; called by muse, mutect2, varscan2
- MFSD10 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs202141771, COSV99296416; called by muse, mutect2, varscan2
- MGAT3 | c.384del p.P130Rfs*24 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs768261467, COSV57864436; called by mutect2, pindel, varscan2
- MIDEAS | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 24/67 reads (36%) | catalogued as COSV54098459; called by muse, mutect2, varscan2
- MIS18BP1 | c.1139del p.N380Ifs*3 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs751180035; called by mutect2, varscan2
- MLNR | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs141878008; called by muse, mutect2, varscan2
- MN1 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.15); catalogued as COSV56560143; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 56/176 reads (32%) | catalogued as rs755830405; called by mutect2, varscan2
- MOGAT2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 89/234 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs772095311, COSV52220919, COSV52221483; called by muse, mutect2, varscan2
- MON2 | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409435535, COSV54803293; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 25/98 reads (26%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRPL44 | c.995G>A p.S332N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1361084941, COSV51315989; called by muse, mutect2, varscan2
- MTA2 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.086); catalogued as COSV53472071; called by muse, mutect2, varscan2
- MTMR2 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 189/538 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs750836112, COSV57687680; called by muse, mutect2, varscan2
- MTMR9 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201123937, COSV55311625; called by muse, mutect2, varscan2
- MTOR | c.2146G>A p.G716S | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as COSV63875842; called by muse, mutect2, varscan2
- MTREX | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777788705; called by muse, mutect2, varscan2
- MTRF1L | c.260-6del | Splice Region (DEL) | VAF 3/30 reads (10%) | catalogued as rs750386363; called by pindel, varscan2
- MTSS1 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 66/284 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV100274720; called by muse, mutect2, varscan2
- MUC17 | c.5711T>C p.V1904A | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200243186; called by muse, varscan2
- MVP | c.199C>T p.R67W | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746545141; called by muse, mutect2, varscan2
- MYO10 | c.5120A>G p.H1707R | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs757499312; called by muse, mutect2, varscan2
- MYO1E | c.780C>T p.H260= | Splice Region (SNP) | VAF 79/263 reads (30%) | catalogued as rs764092322; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYO5B | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 161/514 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV53226888; called by muse, mutect2, varscan2
- MYOF | c.515C>T p.T172M | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs540906575, COSV63706649; called by muse, mutect2, varscan2
- NAP1L3 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766911140, COSV59075817; called by mutect2, varscan2
- NAT16 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs781324827; called by muse, mutect2, varscan2
- NAV3 | c.3659C>T p.S1220F | Missense Mutation (SNP) | VAF 51/192 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781297578; called by muse, mutect2, varscan2
- NBEAL2 | c.6659_6661del p.F2220del | In Frame Del (DEL) | VAF 42/210 reads (20%) | catalogued as rs776748718; called by pindel, varscan2
- NCK2 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs1196796618, COSV99255091; called by muse, mutect2, varscan2
- NCOR2 | c.300G>A p.M100I | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs938084113; called by muse, mutect2, varscan2
- NELFA | c.491C>T p.A164V (on ENST00000542778; = p.A153V on NM_005663.5) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1446644319, COSV100424611; called by muse, mutect2, varscan2
- NEMF | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 35/99 reads (35%) | catalogued as rs756145153, COSV100027949, COSV53590017; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEURL4 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.267); catalogued as rs749682457; called by muse, mutect2, varscan2
- NID1 | c.1536C>T p.T512= | Splice Region (SNP) | VAF 29/79 reads (37%) | catalogued as rs146116073; called by muse, mutect2, varscan2
- NOTCH3 | c.6311C>T p.S2104L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1408330704; called by muse, mutect2, varscan2
- NPIPB6 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 97/572 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as rs749463761; called by muse, mutect2, varscan2
- NPPB | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.012); catalogued as rs143526178, COSV64687549; called by muse, mutect2, varscan2
- NR4A2 | c.325dup p.Q109Pfs*3 | Frame Shift Ins (INS) | VAF 48/188 reads (26%) | catalogued as rs774629025; called by mutect2, varscan2
- NRBP1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs919186043; called by muse, mutect2, varscan2
- NRXN1 | c.1851dup p.L618Afs*5 | Frame Shift Ins (INS) | VAF 9/49 reads (18%) | catalogued as rs768883697; called by mutect2, varscan2
- NUP214 | c.3058C>T p.R1020C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140330621; called by muse, mutect2, varscan2
- NYAP1 | c.545dup p.G183Rfs*16 | Frame Shift Ins (INS) | VAF 30/118 reads (25%) | catalogued as rs751811587; called by mutect2, pindel, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 42/181 reads (23%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OPTN | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 30/221 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1003009434, COSV53810036; called by muse, mutect2, varscan2
- OR13C9 | c.33A>T p.E11D | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs144981085, COSV52242591; called by muse, mutect2, varscan2
- OR2A14 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 140/490 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV101376493; called by muse, mutect2, varscan2
- OR2T33 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 130/643 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1294408405, COSV100531467; called by muse, mutect2, varscan2
- OR2W3 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs754327817; called by muse, mutect2, varscan2
- OR5C1 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs369118602; called by muse, mutect2, varscan2
- OR5M8 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs201389871; called by muse, mutect2, varscan2
- OR6B1 | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV68770181; called by muse, mutect2, varscan2
- OR6P1 | c.96del p.F32Lfs*6 | Frame Shift Del (DEL) | VAF 39/98 reads (40%) | catalogued as rs201077183; called by mutect2, varscan2
- OR8D2 | c.491C>A p.S164* | Nonsense Mutation (SNP) | VAF 31/382 reads (8%) | catalogued as COSV100659147; called by muse, mutect2
- OSER1 | c.389G>A p.S130N | Missense Mutation (SNP) | VAF 118/381 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs771879436; called by muse, mutect2, varscan2
- OTUD7A | c.1544C>T p.T515M (on ENST00000307050 / NM_001382637.1; = p.T508M on NM_130901.3) | Missense Mutation (SNP) | VAF 132/421 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as rs777504137; called by muse, mutect2, varscan2
- PAPPA2 | c.1229del p.G410Efs*47 | Frame Shift Del (DEL) | VAF 102/304 reads (34%) | catalogued as COSV62772783; called by mutect2, pindel, varscan2
- PARD3B | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs765556933, COSV100592976; called by muse, mutect2
- PARP15 | c.1142del p.G381Efs*12 (on ENST00000464300 / NM_001113523.3; = p.G147Efs*12 on NM_152615.2) | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs1299504949, COSV100117308; called by mutect2, varscan2
- PCDH15 | c.1945A>G p.T649A | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.145); catalogued as rs370323132; called by muse, mutect2, varscan2
- PCDH17 | c.1223del p.G408Vfs*18 | Frame Shift Del (DEL) | VAF 37/134 reads (28%) | catalogued as COSV64974164; called by mutect2, pindel, varscan2
- PCDHA5 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 128/388 reads (33%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.009); catalogued as COSV65349706; called by muse, mutect2, varscan2
- PCDHB3 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 289/977 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1156469875, COSV50564255; called by muse, mutect2, varscan2
- PCDHB7 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs1554280025, COSV50768388; called by muse, mutect2, varscan2
- PCDHGA6 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 128/512 reads (25%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.003); catalogued as rs749559180, COSV53894058; called by muse, mutect2, varscan2
- PCDHGB6 | c.88A>T p.S30C | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs767669019; called by muse, varscan2
- PCED1A | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 108/416 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754708835, COSV104417826, COSV62314227; called by muse, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCSK1 | c.1130C>A p.T377K | Missense Mutation (SNP) | VAF 87/282 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.155); catalogued as COSV60733666; called by muse, mutect2, varscan2
- PDS5B | c.4169del p.N1390Mfs*4 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as rs759495724; called by mutect2, varscan2
- PER2 | c.2465C>T p.P822L | Missense Mutation (SNP) | VAF 62/197 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs769454492, COSV99611532; called by muse, mutect2, varscan2
- PGR | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99679417; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 29/121 reads (24%) | catalogued as rs749326031; called by mutect2, pindel, varscan2
- PHACTR4 | c.160del p.S54Vfs*12 (on ENST00000373839 / NM_001350159.2; = p.S64Vfs*12 on NM_023923.4) | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | catalogued as rs761437290, COSV65783432; called by mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs769717544; called by mutect2, varscan2
- PHKA1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1556298604; called by muse, varscan2
- PHOX2A | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV53353359; called by muse, mutect2, varscan2
- PIEZO1 | c.4775+8C>T | Splice Region (SNP) | VAF 31/79 reads (39%) | catalogued as rs939309278; called by muse, mutect2, varscan2
- PIK3CA | c.308A>G p.E103G | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV55902181; called by muse, mutect2, varscan2
- PLA2G4A | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV100820699; called by muse, mutect2, varscan2
- PLCH1 | c.142C>T p.R48W (on ENST00000340059 / NM_001130960.2; = p.R60W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs756953423; called by muse, mutect2, varscan2
- PLEC | c.11965G>A p.D3989N (on ENST00000322810 / NM_201380.4; = p.D3879N on NM_000445.5) | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as rs879965060; called by muse, mutect2, varscan2
- PLEC | c.8321C>T p.A2774V (on ENST00000322810 / NM_201380.4; = p.A2664V on NM_000445.5) | Missense Mutation (SNP) | VAF 230/510 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs782384162, COSV59601081, COSV59700377; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA7 | c.3244C>T p.R1082* | Nonsense Mutation (SNP) | VAF 150/509 reads (29%) | catalogued as rs1310781253; called by muse, mutect2, varscan2
- PLSCR5 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs372370688, COSV71649018; called by muse, mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 78/232 reads (34%) | catalogued as rs782247826; called by mutect2, varscan2
- PMPCA | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs1233134648; called by muse, mutect2, varscan2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 136/359 reads (38%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel, varscan2
- PPFIA1 | c.2761C>T p.R921C | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54140643; called by muse, mutect2, varscan2
- PPP1R13L | c.1678G>A p.G560R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs747862057, COSV62908540; called by muse, mutect2, varscan2
- PPP1R26 | c.1598G>A p.S533N | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs759365285; called by muse, mutect2, varscan2
- PRELP | c.73C>T p.R25* | Nonsense Mutation (SNP) | VAF 15/39 reads (38%) | catalogued as rs769225317; called by muse, varscan2
- PRKCG | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1313302986; called by muse, mutect2, varscan2
- PRKDC | c.11290G>A p.V3764M | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as rs756427326, COSV58056587; called by muse, mutect2, varscan2
- PROM2 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.904); catalogued as rs115224562; called by muse, mutect2, varscan2
- PRPH | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.411); catalogued as rs764932638; called by muse, mutect2, varscan2
- PTGDR | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.43); catalogued as rs202080827, COSV60093155; called by muse, mutect2, varscan2
- PTH2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); catalogued as rs868054026, COSV99569597; called by muse, varscan2
- PTPRN | c.356del p.P119Qfs*81 | Frame Shift Del (DEL) | VAF 43/142 reads (30%) | catalogued as rs759562798; called by mutect2, pindel, varscan2
- PTPRN2 | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 24/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66104992; called by muse, mutect2
- RABGEF1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 7/40 reads (18%) | PolyPhen benign (0); catalogued as rs1418924187, COSV53162756; called by muse, mutect2, varscan2
- RADIL | c.2642del p.P881Lfs*110 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs767679528; called by pindel, varscan2
- RADIL | c.2620G>A p.A874T | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs745940804; called by muse, varscan2
- RAET1G | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1371493220; called by muse, mutect2, varscan2
- RANBP17 | c.1884dup p.L629Tfs*17 | Frame Shift Ins (INS) | VAF 40/118 reads (34%) | catalogued as rs779856373; called by mutect2, varscan2
- RASGRF2 | c.1425del p.K476Nfs*12 | Frame Shift Del (DEL) | VAF 21/76 reads (28%) | catalogued as rs1561605146; called by mutect2, pindel, varscan2
- RB1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.099); catalogued as rs181988132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBBP9 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.309); catalogued as rs767629778; called by muse, mutect2, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs762006287; called by mutect2, varscan2
- RESP18 | c.209del p.G70Afs*14 | Frame Shift Del (DEL) | VAF 46/157 reads (29%) | catalogued as COSV61114468; called by mutect2, pindel, varscan2
- RHAG | c.89A>G p.Q30R | Missense Mutation (SNP) | VAF 126/434 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as rs1200674491; called by muse, mutect2, varscan2
- RHOQ | c.577del p.R193Efs*2 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | catalogued as rs1368074831, COSV53191234; called by mutect2, varscan2
- RIOK3 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165065053; called by muse, mutect2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 38/79 reads (48%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 46/176 reads (26%) | catalogued as rs1192824348; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS11 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs11549537, COSV54527032; called by muse, mutect2, varscan2
- RTL9 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 132/383 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV101511823; called by mutect2, varscan2
- RTN2 | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs767185788, COSV55594631; called by muse, mutect2, varscan2
- RYR3 | c.1828del p.V610Lfs*3 | Frame Shift Del (DEL) | VAF 32/97 reads (33%) | catalogued as COSV66794652; called by mutect2, pindel, varscan2
- S100A12 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as rs747910073; called by muse, mutect2, varscan2
- SACS | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1215104195; called by muse, mutect2, varscan2
- SCAF1 | c.3118C>G p.Q1040E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV62183436; called by muse, varscan2
- SCARA3 | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 107/433 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.261); catalogued as rs757129937, COSV57270029; called by muse, mutect2, varscan2
- SCARF2 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769761605; called by muse, mutect2, varscan2
- SCART1 | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375970203; called by muse, mutect2, varscan2
- SDK2 | c.2988dup p.T997Hfs*54 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | catalogued as rs770900315; called by mutect2, pindel, varscan2
- SEC14L5 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs754852146, COSV52037163; called by muse, mutect2, varscan2
- SEC16A | c.319T>C p.C107R | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs758794202; called by muse, varscan2
- SEMA6A | c.3083C>T p.A1028V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.291); catalogued as rs368680094; called by muse, mutect2, varscan2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 13/51 reads (25%) | catalogued as rs1434994276; called by mutect2, pindel, varscan2
- SFXN5 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as rs1180191329; called by muse, mutect2, varscan2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 29/109 reads (27%) | catalogued as rs747473028; called by mutect2, varscan2
- SIGMAR1 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 121/411 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs777843655, COSV52844815; called by muse, mutect2, varscan2
- SLA | c.73G>A p.D25N (on ENST00000338087 / NM_001045556.3; = p.D65N on NM_006748.4) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.902); catalogued as rs148579032; called by muse, mutect2, varscan2
- SLC12A5 | c.2364del p.L789Cfs*38 (on ENST00000454036 / NM_001134771.2; = p.L766Cfs*38 on NM_020708.5) | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs1568866957; called by mutect2, varscan2
- SLC12A7 | c.2056del p.H686Tfs*11 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | catalogued as rs767964038; called by mutect2, pindel, varscan2
- SLC13A2 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1555603997; called by muse, mutect2, varscan2
- SLC22A9 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as rs746534547; called by muse, mutect2, varscan2
- SLC25A2 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs1554296131; called by muse, mutect2, varscan2
- SLC30A10 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV63070475; called by muse, mutect2, varscan2
- SLC30A3 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs543736904, COSV99273715; called by muse, mutect2, varscan2
- SLC46A1 | c.905A>G p.K302R | Missense Mutation (SNP) | VAF 22/368 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1555590482; called by muse, mutect2
- SLC4A3 | c.1500del p.S502Afs*2 | Frame Shift Del (DEL) | VAF 52/147 reads (35%) | catalogued as rs1559200713; called by mutect2, pindel, varscan2
- SLC4A3 | c.2536G>A p.V846M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs111420029; called by muse, varscan2
- SLC6A15 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as COSV57022477; called by muse, mutect2, varscan2
- SLCO3A1 | c.1115del p.L372Wfs*22 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | catalogued as rs34062402; called by mutect2, pindel, varscan2
- SLITRK5 | c.20dup p.V8Sfs*13 | Frame Shift Ins (INS) | VAF 12/49 reads (24%) | catalogued as rs756270612; called by mutect2, pindel, varscan2
- SLTM | c.1940G>A p.R647H | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1356307895, COSV51054521; called by muse, mutect2, varscan2
- SMC6 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs1007197167, COSV61177605; called by muse, mutect2, varscan2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 27/74 reads (36%) | catalogued as rs758895137; called by mutect2, varscan2
- SNAI2 | c.115A>G p.M39V | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99195051; called by muse, mutect2, varscan2
- SNED1 | c.2707G>A p.A903T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs751755887, COSV60025369; called by muse, mutect2, varscan2
- SPDYE5 | c.185dup p.C63Mfs*2 | Frame Shift Ins (INS) | VAF 46/183 reads (25%) | catalogued as rs1554482318; called by mutect2, pindel, varscan2
- SPEF2 | c.2657del p.K886Rfs*8 | Frame Shift Del (DEL) | VAF 12/23 reads (52%) | catalogued as rs750890082; called by mutect2, varscan2
- SPRN | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.086); catalogued as rs1288099042; called by muse, varscan2
- SRRM2 | c.2735C>G p.S912* | Nonsense Mutation (SNP) | VAF 54/203 reads (27%) | catalogued as rs756819488; called by muse, mutect2, varscan2
- SRRM4 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 70/247 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV57410378; called by muse, mutect2, varscan2
- SSPN | c.44del p.G15Afs*53 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | catalogued as rs981783070; called by mutect2, pindel, varscan2
- STAR | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 93/385 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1237961867, COSV52417399; called by muse, mutect2, varscan2
- STON1 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs771669182; called by muse, mutect2, varscan2
- SWAP70 | c.305del p.N102Tfs*31 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as rs749995893; called by mutect2, varscan2
- SYDE1 | c.635del p.G212Afs*129 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | catalogued as rs1214190235; called by mutect2, pindel, varscan2
- SYNE4 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1213954408; called by muse, mutect2, varscan2
- SYT7 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs750697898, COSV55655549; called by muse, mutect2, varscan2
- SYTL1 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 68/207 reads (33%) | catalogued as rs759430700, COSV100539252, COSV100539617; called by muse, mutect2, varscan2
- SZT2 | c.3268G>A p.G1090S (on ENST00000634258 / NM_001365999.1; = p.G1033S on NM_015284.4) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1409656203; called by muse, mutect2, varscan2
- TAS1R2 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.695); catalogued as rs769955901; called by muse, mutect2, varscan2
- TBC1D14 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs374685226, COSV68985597; called by muse, mutect2, varscan2
- TBC1D8 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.4); PolyPhen probably damaging (1); catalogued as rs768933731, COSV65212284; called by muse, mutect2, varscan2
- TBX3 | c.1678G>A p.A560T (on ENST00000257566 / NM_016569.4; = p.A540T on NM_005996.4) | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1219837774; called by muse, mutect2, varscan2
- TCF7L2 | c.1454del p.K485Sfs*23 (on ENST00000355995 / NM_001367943.1; = p.K462Sfs*23 on NM_030756.5) | Frame Shift Del (DEL) | VAF 38/94 reads (40%) | catalogued as rs745872748; called by mutect2, varscan2
- TCTE1 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 78/253 reads (31%) | catalogued as rs763824437; called by muse, mutect2, varscan2
- TEX14 | c.4143del p.E1382Kfs*82 (on ENST00000240361 / NM_001201457.2; = p.E1336Kfs*82 on NM_031272.5) | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs753440975; called by mutect2, pindel, varscan2
- TEX2 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs782450553, COSV51978970; called by muse, mutect2, varscan2
- TEX44 | c.770G>T p.R257M | Missense Mutation (SNP) | VAF 78/249 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100009890; called by muse, mutect2, varscan2
- TFAP2C | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as rs773514336, COSV52373135; called by muse, mutect2
- THAP7 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1433449610; called by muse, mutect2, varscan2
- TICAM1 | c.1925dup p.P643Tfs*123 | Frame Shift Ins (INS) | VAF 6/19 reads (32%) | catalogued as rs762126373; called by mutect2, varscan2
- TLR9 | c.792del p.C265Afs*19 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | catalogued as COSV62347846; called by mutect2, pindel, varscan2
- TMED7 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1009601806, COSV99143256; called by muse, mutect2, varscan2
- TMEM131 | c.3827C>T p.A1276V | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as rs773147161, COSV51784469; called by muse, mutect2, varscan2
- TMEM200C | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1437869511, COSV101274883; called by muse, varscan2
- TMEM8B | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs969693098, COSV65076800; called by muse, mutect2, varscan2
- TNIP3 | c.842T>C p.V281A | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs762906174; called by muse, mutect2, varscan2
- TNRC6A | c.4796C>T p.S1599L | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1398473171, COSV59364050; called by muse, mutect2, varscan2
- TNS1 | c.1393T>C p.S465P | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1559231335; called by muse, mutect2, varscan2
- TNXB | c.7966C>T p.P2656S (on ENST00000647633; = p.P2409S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV64477768; called by muse, mutect2, varscan2
- TNXB | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 151/512 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs1199728115; called by muse, mutect2, varscan2
- TOP2A | c.4480del p.E1494Rfs*26 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as COSV68503049; called by mutect2, pindel, varscan2
- TRAM2 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs750740962; called by muse, mutect2, varscan2
- TRAP1 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs776610264; called by muse, mutect2, varscan2
- TRBV4-1 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs1252150973; called by muse, mutect2, varscan2
- TRIM2 | c.439G>A p.A147T (on ENST00000437508; = p.A174T on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as rs200706275; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM33 | c.503del p.G168Afs*11 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as COSV100635817; called by mutect2, pindel, varscan2
- TRIP11 | c.2123del p.N708Tfs*7 | Frame Shift Del (DEL) | VAF 50/165 reads (30%) | catalogued as rs747106242; called by mutect2, pindel, varscan2
- TRIP12 | c.5093G>A p.R1698H | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs907098852, COSV52263686; called by muse, mutect2, varscan2
- TRIT1 | c.244A>G p.M82V | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs775916635; called by muse, mutect2, varscan2
- TRPM1 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as rs750109963, CM158233, COSV56640995; called by muse, mutect2, varscan2
- TTC21B | c.1979A>G p.N660S | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54633024; called by muse, mutect2
- TTC7A | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs531344750, COSV55408463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 17/24 reads (71%) | catalogued as rs760251146; called by mutect2, varscan2
- UBASH3B | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 31/116 reads (27%) | catalogued as rs375615215; called by muse, mutect2, varscan2
- UBE3B | c.3070C>T p.R1024W | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs776429830, COSV61074792; called by muse, mutect2, varscan2
- UBXN4 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769939888; called by muse, mutect2, varscan2
- UHRF1BP1 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1055384322; called by muse, mutect2, varscan2
- UHRF1BP1 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.412); catalogued as rs1164011565; called by muse, mutect2, varscan2
- ULK1 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs374085741; called by muse, mutect2, varscan2
- ULK2 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs749044855; called by muse, mutect2, varscan2
- UNC13A | c.4961C>T p.P1654L | Missense Mutation (SNP) | VAF 132/306 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs577178783; called by muse, mutect2, varscan2
- UNC13D | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 92/265 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1006825019, COSV52884676; called by muse, mutect2, varscan2
- USP17L7 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 135/1180 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1339259945; called by mutect2, varscan2
- USP36 | c.2543A>G p.K848R | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.024); catalogued as rs768866105; called by muse, mutect2, varscan2
- VDR | c.1205G>A p.R402H | Missense Mutation (SNP) | VAF 135/413 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV57467107, COSV57467803; called by muse, mutect2, varscan2
- VPS13D | c.1616C>T p.S539F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV62533448; called by muse, mutect2, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs756221452; called by mutect2, varscan2
- VPS54 | c.2157del p.K719Nfs*30 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs778598752; called by mutect2, varscan2
- VPS8 | c.1033C>T p.R345W (on ENST00000625842 / NM_001349294.1; = p.R343W on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs535949463; called by muse, mutect2, varscan2
- WDFY4 | c.9056G>A p.R3019H | Missense Mutation (SNP) | VAF 152/435 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs969942181; called by muse, mutect2, varscan2
- WDHD1 | c.508T>C p.C170R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.312); catalogued as rs768466067; called by muse, mutect2, varscan2
- WDR13 | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs782721320; called by muse, mutect2, varscan2
- WDR45B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 63/202 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753663465, COSV101124421, COSV66408248; called by muse, mutect2, varscan2
- WIZ | c.3680C>T p.P1227L | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs903382924; called by muse, mutect2, varscan2
- WNK1 | c.6233G>A p.R2078Q (on ENST00000315939 / NM_018979.4; = p.R1830Q on NM_014823.3) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1043098905; called by muse, mutect2, varscan2
- WTAP | c.918_920del p.P307del | In Frame Del (DEL) | VAF 41/153 reads (27%) | catalogued as rs1316322175; called by mutect2, pindel, varscan2
- YBEY | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1031150685, COSV52450015; called by muse, mutect2, varscan2
- YEATS2 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as rs759531876, COSV59363392; called by muse, mutect2, varscan2
- ZC3H18 | c.2037dup p.R680Qfs*14 | Frame Shift Ins (INS) | VAF 24/111 reads (22%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDHHC24 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.599); catalogued as rs764101150; called by muse, mutect2, varscan2
- ZKSCAN7 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs750023286, COSV56272140; called by muse, mutect2, varscan2
- ZNF181 | c.1181G>C p.R394P | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.234); catalogued as rs559196878; called by muse, mutect2, varscan2
- ZNF202 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 75/232 reads (32%) | catalogued as rs746672806; called by muse, mutect2, varscan2
- ZNF226 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as rs371422117; called by muse, mutect2, varscan2
- ZNF496 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs746790114; called by muse, mutect2, varscan2
- ZNF560 | c.1699G>A p.A567T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142348936; called by mutect2, varscan2
- ZNF707 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs782325840; called by muse, mutect2, varscan2
- ZNF92 | c.767C>T p.P256L (on ENST00000328747 / NM_152626.4; = p.P187L on NM_007139.4) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.234); catalogued as rs745469475, COSV60876701; called by mutect2, varscan2
- AATF | c.68A>G p.D23G | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AC126283.2 | c.864dup p.D289Rfs*2 | Frame Shift Ins (INS) | VAF 53/224 reads (24%) | called by mutect2, pindel, varscan2
- ACAP3 | c.2336C>A p.A779E | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACKR4 | c.526del p.Y176Ifs*3 | Frame Shift Del (DEL) | VAF 101/427 reads (24%) | called by mutect2, pindel, varscan2
- ACSL3 | c.64_66del p.L23del | In Frame Del (DEL) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- ACTA2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 69/310 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ADAM19 | c.1586G>T p.W529L | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS12 | c.1598C>T p.T533I | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRA3 | c.2571del p.A858Lfs*22 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- ADGRE5 | c.2344_2346del p.L782del (on ENST00000242786 / NM_078481.4; = p.L689del on NM_001784.5) | In Frame Del (DEL) | VAF 38/111 reads (34%) | called by mutect2, pindel, varscan2
- ADGRF3 | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ADGRF5 | c.2930A>G p.E977G | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- AHI1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP17A | c.430dup p.E144Gfs*36 | Frame Shift Ins (INS) | VAF 9/72 reads (13%) | called by mutect2, pindel, varscan2
- AKAP8 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- AP2A2 | c.1088A>C p.E363A | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- AP5B1 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- APC2 | c.5675del p.P1892Rfs*104 | Frame Shift Del (DEL) | VAF 20/47 reads (43%) | called by mutect2, varscan2
- APOB | c.1622A>G p.Q541R | Missense Mutation (SNP) | VAF 90/265 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARFGEF3 | c.2523G>T p.E841D | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ARHGAP11A | c.1099G>C p.V367L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ARHGEF26 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, varscan2
- ATG2A | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 119/261 reads (46%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATP6V0A2 | c.1344del p.F448Lfs*9 | Frame Shift Del (DEL) | VAF 97/332 reads (29%) | called by mutect2, pindel, varscan2
- ATP6V1E2 | c.485A>G p.H162R | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- AUTS2 | c.427A>G p.S143G | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- AXIN2 | c.2393del p.K798Rfs*63 | Frame Shift Del (DEL) | VAF 88/320 reads (28%) | called by mutect2, pindel, varscan2
- B3GAT1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 75/257 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- BAIAP3 | c.2227T>C p.C743R | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BHLHE40 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- BID | c.89T>C p.L30P | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTN2A2 | c.1291T>A p.S431T | Missense Mutation (SNP) | VAF 127/501 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BUD31 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- C10orf90 | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- C17orf80 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- C2orf76 | c.280A>G p.S94G | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, varscan2
- C3orf85 | c.94T>C p.F32L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C6orf201 | c.190del p.R64Efs*7 | Frame Shift Del (DEL) | VAF 76/215 reads (35%) | called by mutect2, pindel, varscan2
- CACNA1D | c.3044T>C p.I1015T (on ENST00000350061 / NM_001128840.3; = p.I1035T on NM_000720.4) | Missense Mutation (SNP) | VAF 107/322 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CACNB4 | c.470T>G p.L157W | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAMK2N2 | c.227C>A p.P76Q | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- CAND1 | c.747A>G p.I249M | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- CAND1 | c.1565C>A p.P522H | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CASP8 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CASR | c.2660A>G p.Q887R (on ENST00000490131; = p.Q964R on NM_000388.4) | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- CATSPERB | c.1447A>C p.S483R | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC88B | c.3832C>A p.L1278M | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, varscan2
- CCR1 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 59/172 reads (34%) | called by muse, mutect2, varscan2
- CDADC1 | c.1415A>G p.Q472R | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CDC40 | c.578del p.L193Wfs*13 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | called by mutect2, pindel, varscan2
- CDCP1 | c.2162del p.K721Sfs*96 | Frame Shift Del (DEL) | VAF 90/270 reads (33%) | called by mutect2, pindel, varscan2
- CDCP1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 64/203 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CDH24 | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CDK14 | c.681del p.L228Cfs*6 (on ENST00000380050 / NM_001287135.2; = p.L210Cfs*6 on NM_012395.3) | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- CDK18 | c.922del p.E308Sfs*2 (on ENST00000506784 / NM_212503.3; = p.E278Sfs*2 on NM_002596.4) | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- CDR2 | c.1157C>T p.A386V | Missense Mutation (SNP) | VAF 99/298 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CELF2 | c.1145C>T p.A382V (on ENST00000416382 / NM_001025077.3; = p.A395V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- CENPE | c.3595A>G p.T1199A | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2
- CENPH | c.344del p.N115Tfs*16 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- CEP78 | c.458T>A p.L153Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CES4A | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2
- CGN | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CHD7 | c.6392_6393del p.F2131Cfs*8 | Frame Shift Del (DEL) | VAF 146/706 reads (21%) | called by mutect2, pindel, varscan2
- CHD9 | c.1744del p.T582Qfs*7 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- CHPF2 | c.509_510dup p.F171Tfs*38 | Frame Shift Ins (INS) | VAF 48/208 reads (23%) | called by mutect2, varscan2
- CHSY3 | c.636del p.N213Tfs*29 | Frame Shift Del (DEL) | VAF 78/238 reads (33%) | called by pindel, varscan2
- CIAO2A | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- CLCNKB | c.855dup p.V286Cfs*29 | Frame Shift Ins (INS) | VAF 67/231 reads (29%) | called by mutect2, varscan2
- CLDN15 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLEC19A | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CLVS2 | c.616T>C p.Y206H | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CMTM7 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 45/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CNOT3 | c.1805T>C p.L602P | Missense Mutation (SNP) | VAF 161/480 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL18A1 | c.1874del p.G625Efs*10 (on ENST00000359759 / NM_130444.3; = p.G390Efs*10 on NM_030582.4) | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- COL21A1 | c.2479C>A p.P827T | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- COQ7 | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPED1 | c.2731C>T p.Q911* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- CPNE4 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 123/395 reads (31%) | called by muse, mutect2, varscan2
- CRACDL | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CREBBP | c.4268dup p.P1424Sfs*13 | Frame Shift Ins (INS) | VAF 78/272 reads (29%) | called by mutect2, pindel, varscan2
- CROCC2 | c.3500G>T p.R1167M | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CRYZL1 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- CSMD2 | c.2363A>G p.Y788C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CSMD2 | c.1787A>T p.E596V | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- CSNK1D | c.1072del p.R358Gfs*12 | Frame Shift Del (DEL) | VAF 41/153 reads (27%) | called by mutect2, pindel, varscan2
- CTAGE6 | c.681del p.Q228Sfs*11 | Frame Shift Del (DEL) | VAF 73/292 reads (25%) | called by mutect2, pindel, varscan2
- CTBP1 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 63/192 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CUX1 | c.2731del p.L911Cfs*20 | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- CXXC1 | c.79A>G p.I27V | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP21A2 | c.259del p.A87Qfs*57 | Frame Shift Del (DEL) | VAF 48/206 reads (23%) | called by mutect2, pindel, varscan2
- DBX2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF1 | c.3800A>G p.H1267R | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DCAF4L2 | c.263del p.T88Kfs*2 | Frame Shift Del (DEL) | VAF 66/331 reads (20%) | called by mutect2, pindel, varscan2
- DCP2 | c.335T>C p.V112A | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- DDIT4L | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2
- DHCR24 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 140/430 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHODH | c.243_244del p.R81Sfs*5 | Frame Shift Del (DEL) | VAF 60/217 reads (28%) | called by pindel, varscan2
- DKK2 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 122/426 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMGDH | c.1647A>T p.R549S | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAAF3 | c.7A>G p.T3A (on ENST00000524407 / NM_001256715.2; = p.T50A on NM_178837.4) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- DNAH11 | c.6127G>T p.A2043S | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH12 | c.5874del p.F1958Lfs*2 (on ENST00000351747; = p.F1977Lfs*2 on NM_001366028.2) | Frame Shift Del (DEL) | VAF 19/79 reads (24%) | called by mutect2, pindel, varscan2
- DNAH2 | c.11506C>A p.P3836T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAJC7 | c.1106del p.N369Mfs*6 | Frame Shift Del (DEL) | VAF 30/115 reads (26%) | called by mutect2, pindel, varscan2
- DNMT1 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 151/431 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK6 | c.1963G>T p.G655C | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DPP6 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, varscan2
- DTNB | c.629del p.L210* | Frame Shift Del (DEL) | VAF 25/76 reads (33%) | called by mutect2, pindel, varscan2
- DYRK1A | c.124del p.D42Tfs*7 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- DYRK1B | c.1709G>A p.G570D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, varscan2
- DYRK3 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EFCAB13 | c.1625A>G p.K542R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- EFCAB5 | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- EIF4G1 | c.538-4C>A | Splice Region (SNP) | VAF 91/248 reads (37%) | called by muse, mutect2, varscan2
- ELP2 | c.1817A>G p.Q606R | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- EML1 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- EML6 | c.4632del p.V1546Sfs*65 | Frame Shift Del (DEL) | VAF 43/169 reads (25%) | called by mutect2, pindel, varscan2
- EPB41L2 | c.2200T>G p.S734A | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.257); called by mutect2, varscan2
- EPN2 | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- EPS15 | c.922A>T p.I308F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- EPS8 | c.2410del p.I804Sfs*26 | Frame Shift Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- ERBB2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- ESPNL | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EXOC6 | c.1141-2A>G p.X381_splice | Splice Site (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- EYS | c.8306del p.L2769Yfs*5 (on ENST00000370621 / NM_001292009.1; = p.L2748Yfs*5 on NM_001142800.2) | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- EZHIP | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EZHIP | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- FAM240C | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM47B | c.1147del p.W383Gfs*21 | Frame Shift Del (DEL) | VAF 70/246 reads (28%) | called by mutect2, varscan2
- FAM76A | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM76B | c.938del p.N313Tfs*24 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | called by mutect2, pindel, varscan2
- FANCM | c.2589del p.D864Ifs*12 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- FBXL17 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.662); called by muse, mutect2, varscan2
- FERD3L | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.03); called by mutect2, varscan2
- FGD5 | c.3711del p.T1238Pfs*9 | Frame Shift Del (DEL) | VAF 69/237 reads (29%) | called by mutect2, pindel, varscan2
- FHOD3 | c.2819C>T p.S940F (on ENST00000359247 / NM_001281739.3; = p.S957F on NM_025135.5) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FIGN | c.853del p.L285Yfs*16 | Frame Shift Del (DEL) | VAF 48/138 reads (35%) | called by mutect2, pindel
- FLNB | c.7427T>C p.L2476P | Missense Mutation (SNP) | VAF 147/496 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC1 | c.1235C>G p.T412S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- FREM2 | c.3466del p.V1156Wfs*27 | Frame Shift Del (DEL) | VAF 79/321 reads (25%) | called by mutect2, pindel, varscan2
- GALR1 | c.62del p.P21Rfs*22 | Frame Shift Del (DEL) | VAF 31/123 reads (25%) | called by mutect2, pindel, varscan2
- GALR2 | c.977C>T p.A326V | Missense Mutation (SNP) | VAF 109/305 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- GANAB | c.68del p.L23* | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- GIGYF2 | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- GLG1 | c.2116-2A>T p.X706_splice | Splice Site (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- GLI2 | c.3431T>C p.V1144A (on ENST00000361492 / NM_001374353.1; = p.V1161A on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 175/536 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GNAL | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- GOLGA6A | c.962A>G p.Q321R | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- GPC1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GPR150 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.61); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GRIN1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GSC | c.407T>C p.L136P | Missense Mutation (SNP) | VAF 93/239 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- GTF3C1 | c.2299dup p.S767Kfs*2 | Frame Shift Ins (INS) | VAF 26/66 reads (39%) | called by mutect2, varscan2
- GUCY2D | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- H3C4 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); called by muse, varscan2
- HBS1L | c.17del p.P6Lfs*20 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- HDAC6 | c.910A>G p.T304A | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- HELZ2 | c.4197del p.G1400Afs*41 (on ENST00000467148 / NM_001037335.2; = p.G831Afs*41 on NM_033405.3) | Frame Shift Del (DEL) | VAF 103/348 reads (30%) | called by mutect2, pindel, varscan2
- HES1 | c.509del p.P170Hfs*146 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, varscan2
- HHATL | c.1182C>A p.C394* | Nonsense Mutation (SNP) | VAF 20/344 reads (6%) | called by muse, mutect2
- HIC1 | c.658G>A p.A220T (on ENST00000322941 / NM_001098202.1; = p.A201T on NM_006497.4) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- HIVEP1 | c.1136T>C p.V379A | Missense Mutation (SNP) | VAF 61/170 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- HJURP | c.367T>C p.S123P | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); called by mutect2, varscan2
- HLA-DMA | c.211_213del p.F71del | In Frame Del (DEL) | VAF 97/309 reads (31%) | called by pindel, varscan2
- HMBS | c.771+6G>A | Splice Region (SNP) | VAF 120/339 reads (35%) | called by muse, mutect2, varscan2
- HMX3 | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by mutect2, varscan2
- HNF1B | c.1297C>A p.L433I | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- HNF4G | c.508G>T p.A170S (on ENST00000354370 / NM_001330561.2; = p.A217S on NM_004133.5) | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- HOXC6 | c.613A>T p.T205S | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- HOXC9 | c.338del p.G113Afs*105 | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | called by mutect2, pindel, varscan2
- HOXD8 | c.369del p.C124Afs*53 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- HS3ST3A1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- HSPA14 | c.458del p.N153Mfs*17 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- HTT | c.8252C>T p.A2751V | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ICAM5 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- IGHG4 | c.260A>G p.H87R | Missense Mutation (SNP) | VAF 106/725 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL16 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- IL17A | c.4A>T p.T2S | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL17RB | c.672+2T>C p.X224_splice | Splice Site (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- INPP4A | c.1179-2A>G p.X393_splice | Splice Site (SNP) | VAF 131/449 reads (29%) | called by muse, mutect2, varscan2
- INTS2 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- IRAK3 | c.377dup p.K127Qfs*10 | Frame Shift Ins (INS) | VAF 21/82 reads (26%) | called by mutect2, pindel, varscan2
- IRX5 | c.805del p.R269Afs*98 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | called by mutect2, varscan2
- ITGAD | c.2616+2T>G p.X872_splice | Splice Site (SNP) | VAF 62/172 reads (36%) | called by muse, varscan2
- ITGAE | c.3456del p.F1152Lfs*8 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- ITGAV | c.1682del p.G561Dfs*2 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | called by mutect2, pindel, varscan2
- ITIH5 | c.1433T>C p.I478T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- ITPR2 | c.6367C>T p.Q2123* | Nonsense Mutation (SNP) | VAF 37/109 reads (34%) | called by muse, mutect2, varscan2
- ITPR2 | c.5509del p.R1837Gfs*7 | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- ITPR3 | c.7625-2A>G p.X2542_splice | Splice Site (SNP) | VAF 55/151 reads (36%) | called by muse, mutect2, varscan2
- KBTBD11 | c.280C>A p.P94T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.037); called by mutect2, varscan2
- KCNK17 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 118/384 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KDM8 | c.560_562del p.L187del | In Frame Del (DEL) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- KIAA0408 | c.958A>T p.M320L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by mutect2, varscan2
- KIAA0825 | c.2301del p.F767Lfs*27 | Frame Shift Del (DEL) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- KIF14 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.022); called by mutect2, varscan2
- KIF19 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 49/153 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- KIF20B | c.929_931del p.S310del | In Frame Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- KIF27 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 80/215 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.974); called by mutect2, varscan2
- KIR2DL3 | c.532A>T p.N178Y | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- KLF3 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KLHL26 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- KLHL9 | c.44A>G p.H15R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- LARS1 | c.2478dup p.E827* (on ENST00000394434 / NM_020117.11; = p.E800* on NM_016460.3) | Frame Shift Ins (INS) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- LCE1B | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- LCMT2 | c.1778T>C p.V593A | Missense Mutation (SNP) | VAF 69/219 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- LCOR | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | called by muse, mutect2, varscan2
- LIMK2 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- LIN7B | c.392A>G p.H131R | Missense Mutation (SNP) | VAF 103/262 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LLGL1 | c.1373G>T p.R458M | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LMTK3 | c.2434dup p.A812Gfs*728 | Frame Shift Ins (INS) | VAF 16/68 reads (24%) | called by mutect2, varscan2
- LONRF2 | c.1796T>C p.V599A | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LPAR2 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- LRCH2 | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC37A3 | c.3507G>T p.M1169I | Missense Mutation (SNP) | VAF 34/389 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2
- LRRC9 | c.745del p.I249* | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- LRRK1 | c.1940del p.P647Rfs*115 | Frame Shift Del (DEL) | VAF 95/280 reads (34%) | called by mutect2, pindel, varscan2
- LTBP2 | c.5446del p.H1816Tfs*32 | Frame Shift Del (DEL) | VAF 117/420 reads (28%) | called by mutect2, pindel, varscan2
- LTBP3 | c.1709C>A p.T570N | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- MAEA | c.137A>G p.H46R | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MAMLD1 | c.575dup p.N192Kfs*2 | Frame Shift Ins (INS) | VAF 143/431 reads (33%) | called by mutect2, pindel, varscan2
- MAP2K7 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- MAP4K1 | c.1358A>T p.H453L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.018); called by muse, mutect2
- MAPKAPK2 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, varscan2
- MAPKBP1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- MARCHF4 | c.516+2T>C p.X172_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- MARK4 | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MAST3 | c.2954G>A p.S985N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MCAM | c.1300G>T p.A434S | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MCCC1 | c.1372T>C p.Y458H | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MED14 | c.2594T>C p.V865A | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- MED23 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MED26 | c.52_58delinsAT p.A18Ifs*30 | Frame Shift Del (DEL) | VAF 12/48 reads (25%) | called by pindel, varscan2*
- MEIG1 | c.38A>G p.H13R | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFSD14B | c.395+1G>A p.X132_splice | Splice Site (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- MFSD6 | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.5165del p.L1722Wfs*5 | Frame Shift Del (DEL) | VAF 48/139 reads (35%) | called by mutect2, pindel, varscan2
- MICAL3 | c.5356C>G p.Q1786E | Missense Mutation (SNP) | VAF 67/178 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MINDY4 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKI67 | c.6798G>A p.M2266I | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MKRN3 | c.889_890del p.M297Gfs*23 | Frame Shift Del (DEL) | VAF 68/274 reads (25%) | called by pindel, varscan2
- MRI1 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0); called by mutect2, varscan2
- MTCL1 | c.4856G>T p.G1619V (on ENST00000306329 / NM_001378206.1; = p.G1300V on NM_015210.4) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTSS2 | c.1677del p.G560Afs*34 | Frame Shift Del (DEL) | VAF 25/48 reads (52%) | called by mutect2, pindel, varscan2
- MUC2 | c.1350_1351del p.C450* | Frame Shift Del (DEL) | VAF 26/216 reads (12%) | called by pindel, varscan2
- MYH11 | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 192/606 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYT1L | c.3067C>T p.H1023Y | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NBEA | c.3236A>T p.E1079V | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NCKAP5L | c.1815del p.S606Vfs*66 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- NCOA6 | c.5387T>C p.L1796P | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NDST3 | c.1410+2T>C p.X470_splice | Splice Site (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- NDUFAF4 | c.153dup p.G52Rfs*6 | Frame Shift Ins (INS) | VAF 59/232 reads (25%) | called by mutect2, pindel, varscan2
- NDUFAF5 | c.1029del p.K343Nfs*30 | Frame Shift Del (DEL) | VAF 41/144 reads (28%) | called by mutect2, pindel, varscan2
- NELFE | c.18del p.G7Dfs*2 | Frame Shift Del (DEL) | VAF 39/167 reads (23%) | called by mutect2, pindel, varscan2
- NFE2L3 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NGRN | c.79del p.V27Wfs*31 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/36 reads (72%) | called by mutect2, varscan2
- NKAPL | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP2 | c.1246del p.E416Rfs*35 | Frame Shift Del (DEL) | VAF 118/396 reads (30%) | called by mutect2, varscan2
- NLRP2 | c.3176A>G p.D1059G | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- NMT2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOD1 | c.2680G>A p.V894I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR1I2 | c.751T>C p.F251L | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NSRP1 | c.257del p.K86Rfs*23 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- NUDT11 | c.143C>T p.P48L | Missense Mutation (SNP) | VAF 95/278 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP42 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- NUP98 | c.4340G>A p.S1447N (on ENST00000359171 / NM_001365126.1; = p.S1430N on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
675 further variants in this file (189 protein-altering or splice-affecting, 277 silent, 209 other) are not listed here.
